Somatic mutation profile of tumor specimen C3N-00495-01 (aliquot CPT0078510009) from CPTAC case C3N-00495, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 67.4 years (24,624 days).
Specimen C3N-00495-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 823a9d72-a862-478a-bfbf-54a10311fa71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00495-31 (Blood Derived Normal), aliquot CPT0078570002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f90b8cfe-3e76-43e2-8049-d9f75c1a36d2

The open-access MAF lists 97 somatic variants for this specimen: 69 protein-altering or splice-affecting, 16 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 16, Frame Shift Del 11, Intron 7, 3'UTR 4, Frame Shift Ins 4, Nonsense Mutation 2, Splice Region 1, Splice Site 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY6 | c.3479A>G p.Y1160C | Missense Mutation (SNP) | VAF 90/498 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765207297; called by muse, mutect2, varscan2
- CCAR2 | c.2287C>T p.R763C | Missense Mutation (SNP) | VAF 54/331 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs1459690274; called by muse, mutect2, varscan2
- CHD3 | c.4149_4152del p.S1384Rfs*40 | Frame Shift Del (DEL) | VAF 6/81 reads (7%) | catalogued as rs1465842909; called by mutect2, pindel
- CSMD3 | c.7223C>T p.T2408M (on ENST00000297405 / NM_001363185.1; = p.T2304M on NM_052900.3) | Missense Mutation (SNP) | VAF 37/262 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as rs370458785; called by muse, mutect2, varscan2
- FBXO40 | c.915G>T p.K305N | Missense Mutation (SNP) | VAF 67/303 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as COSV57523601; called by muse, mutect2, varscan2
- FITM1 | c.367A>G p.R123G | Missense Mutation (SNP) | VAF 70/277 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV52823802; called by muse, mutect2, varscan2
- ITIH5 | c.566T>A p.V189E | Missense Mutation (SNP) | VAF 92/472 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV56903999; called by muse, mutect2, varscan2
- ITLN1 | c.227del p.G76Vfs*92 | Frame Shift Del (DEL) | VAF 34/155 reads (22%) | catalogued as COSV58274815; called by mutect2, pindel
- KEAP1 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as COSV50641580; called by muse, mutect2, varscan2
- LENG8 | c.881A>G p.K294R | Missense Mutation (SNP) | VAF 122/587 reads (21%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.98); catalogued as COSV58728752; called by muse, mutect2, varscan2
- NDUFS8 | c.111G>A p.K37= | Splice Region (SNP) | VAF 75/405 reads (19%) | catalogued as rs1006734781; called by muse, mutect2, varscan2
- POLR1A | c.4822A>G p.I1608V | Missense Mutation (SNP) | VAF 74/480 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1350181904; called by muse, mutect2, varscan2
- PTPN3 | c.979A>G p.M327V | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs759874495; called by muse, mutect2, varscan2
- RTKN | c.353G>A p.R118H (on ENST00000272430 / NM_001015055.2; = p.R105H on NM_033046.2) | Missense Mutation (SNP) | VAF 87/233 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as rs766056590, COSV51961066; called by muse, mutect2, varscan2
- RXFP4 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 55/290 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100562586; called by muse, mutect2, varscan2
- SPINK14 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as rs375216023; called by muse, mutect2, varscan2
- SYCE1L | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1242463951; called by muse, mutect2, varscan2
- VHL | c.370A>C p.T124P | Missense Mutation (SNP) | VAF 118/348 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM138551, COSV56544507, COSV56549563; called by muse, mutect2, varscan2
- ADAM18 | c.843del p.K282Nfs*27 | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | called by mutect2, pindel
- AL592490.1 | c.613A>C p.N205H | Missense Mutation (SNP) | VAF 64/359 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- ANK3 | c.3359A>C p.K1120T (on ENST00000280772 / NM_001320874.2; = p.K254T on NM_001149.3) | Missense Mutation (SNP) | VAF 47/222 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AUTS2 | c.473T>C p.L158P | Missense Mutation (SNP) | VAF 246/596 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCL2L13 | c.713_716del p.P238Rfs*5 | Frame Shift Del (DEL) | VAF 50/365 reads (14%) | called by mutect2, pindel, varscan2
- CAND1 | c.1543C>T p.P515S | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CDK16 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EEF1G | c.733del p.Q245Rfs*93 | Frame Shift Del (DEL) | VAF 119/602 reads (20%) | called by mutect2, pindel, varscan2
- EXOC1L | c.323A>T p.Y108F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAM214A | c.2768T>A p.F923Y | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- FANCG | c.252G>T p.L84F | Missense Mutation (SNP) | VAF 131/692 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- FOXO1 | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 24/112 reads (21%) | called by muse, mutect2, varscan2
- GNPTAB | c.247A>T p.N83Y | Missense Mutation (SNP) | VAF 95/457 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPBP1L1 | c.1225C>G p.P409A | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- ITGA5 | c.2226+1G>A p.X742_splice | Splice Site (SNP) | VAF 41/207 reads (20%) | called by muse, mutect2, varscan2
- KDM5C | c.2361del p.K788Sfs*7 | Frame Shift Del (DEL) | VAF 188/457 reads (41%) | called by mutect2, pindel, varscan2
- KIAA1755 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 108/587 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- KMT2A | c.9854T>G p.I3285S | Missense Mutation (SNP) | VAF 42/223 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LRP1 | c.7600_7602del p.N2534del | In Frame Del (DEL) | VAF 56/271 reads (21%) | called by mutect2, pindel, varscan2
- MSANTD3 | c.440G>C p.R147T | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MUC4 | c.14184del p.S4729Qfs*43 (on ENST00000463781 / NM_018406.7; = p.S493Qfs*43 on NM_004532.6) | Frame Shift Del (DEL) | VAF 14/106 reads (13%) | called by mutect2, pindel
- MYO9A | c.4534A>G p.M1512V | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- MYOCD | c.2069dup p.L690Ffs*5 | Frame Shift Ins (INS) | VAF 8/88 reads (9%) | called by mutect2, pindel
- NCAPD2 | c.4057C>T p.Q1353* | Nonsense Mutation (SNP) | VAF 56/406 reads (14%) | called by muse, mutect2, varscan2
- NDST2 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 118/561 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NKAPD1 | c.623_624del p.K208Ifs*18 (on ENST00000280352 / NM_001082970.2; = p.K209Ifs*18 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 29/103 reads (28%) | called by mutect2, pindel, varscan2
- NRCAM | c.3541A>C p.I1181L (on ENST00000379028 / NM_001371124.1; = p.I1060L on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 92/244 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- NUDCD1 | c.846_847insCA p.T283Qfs*6 | Frame Shift Ins (INS) | VAF 5/40 reads (13%) | called by mutect2, pindel
- OPTN | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 37/240 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- OR52A1 | c.107T>A p.I36N | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PDE2A | c.1610C>G p.A537G | Missense Mutation (SNP) | VAF 72/350 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.908); called by muse, varscan2
- PHLDB1 | c.2995del p.L999Wfs*37 | Frame Shift Del (DEL) | VAF 27/132 reads (20%) | called by mutect2, pindel, varscan2
- PKN3 | c.52G>T p.D18Y | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- PM20D2 | c.1253T>C p.I418T | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- PODXL | c.798dup p.T267Yfs*72 | Frame Shift Ins (INS) | VAF 67/160 reads (42%) | called by mutect2, pindel, varscan2
- PPP1R3A | c.229G>T p.V77F | Missense Mutation (SNP) | VAF 25/159 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- PRR29 | c.436A>C p.I146L | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.269); called by muse, varscan2
- PSD3 | c.2219T>C p.V740A (on ENST00000440756; = p.V739A on NM_015310.4) | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RIF1 | c.6336A>C p.E2112D | Missense Mutation (SNP) | VAF 71/230 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- RSPH3 | c.685G>C p.A229P (on ENST00000252655; = p.A87P on NM_031924.8) | Missense Mutation (SNP) | VAF 36/267 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SFMBT1 | c.1182C>G p.N394K | Missense Mutation (SNP) | VAF 67/260 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SHPK | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 73/338 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC13A2 | c.733G>T p.V245L | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- SLC35F1 | c.464_465insA p.T156Dfs*61 | Frame Shift Ins (INS) | VAF 4/50 reads (8%) | called by mutect2, pindel
- THBS3 | c.2239G>A p.V747I | Missense Mutation (SNP) | VAF 46/245 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- TRIM24 | c.2435C>G p.P812R (on ENST00000343526 / NM_015905.3; = p.P778R on NM_003852.4) | Missense Mutation (SNP) | VAF 113/252 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- UBAP2L | c.1321G>C p.A441P | Missense Mutation (SNP) | VAF 82/441 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- UBAP2L | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 84/444 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP3 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 63/369 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- WDR97 | c.2658del p.S887Pfs*86 | Frame Shift Del (DEL) | VAF 78/347 reads (22%) | called by mutect2, pindel
- ZNF496 | c.1294del p.E432Rfs*23 | Frame Shift Del (DEL) | VAF 56/250 reads (22%) | called by mutect2, pindel, varscan2
- BCL2L1 | c.300G>T p.R100= | Silent (SNP) | VAF 120/583 reads (21%) | called by muse, mutect2, varscan2
- CYP4F3 | c.1326C>G p.P442= | Silent (SNP) | VAF 35/152 reads (23%) | called by muse, mutect2, varscan2
- CYTH2 | c.540G>A p.Q180= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as rs1258082107; called by muse, mutect2, varscan2
- EFNB3 | c.726G>A p.V242= | Silent (SNP) | VAF 5/91 reads (5%) | catalogued as rs1307563417; called by muse, mutect2
- GSTO2 | c.687C>T p.L229= | Silent (SNP) | VAF 71/373 reads (19%) | called by muse, mutect2, varscan2
- IGKV1-5 | c.195C>A p.A65= | Silent (SNP) | VAF 279/823 reads (34%) | called by muse, mutect2, varscan2
- IGSF5 | c.1221A>G p.V407= | Silent (SNP) | VAF 37/190 reads (19%) | called by muse, mutect2, varscan2
- LBX2 | c.501G>C p.L167= (on ENST00000377566 / NM_001282430.2; = p.L163= on NM_001009812.2) | Silent (SNP) | VAF 37/266 reads (14%) | catalogued as COSV52034860; called by muse, mutect2, varscan2
- MROH9 | c.2434C>T p.L812= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as rs1052664643; called by muse, mutect2
- MUC4 | c.15558C>G p.A5186= (on ENST00000463781 / NM_018406.7; = p.A950= on NM_004532.6) | Silent (SNP) | VAF 41/270 reads (15%) | called by muse, mutect2, varscan2
- MYO15A | c.2811A>G p.Q937= | Silent (SNP) | VAF 20/133 reads (15%) | catalogued as rs1330388241; called by muse, mutect2
- NACC1 | c.1404C>G p.R468= | Silent (SNP) | VAF 75/415 reads (18%) | called by muse, mutect2, varscan2
- OR52A1 | c.108T>A p.I36= | Silent (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
- PPP2R1B | c.1980G>T p.V660= | Silent (SNP) | VAF 33/184 reads (18%) | called by muse, mutect2, varscan2
- SCN1A | c.1500G>T p.R500= | Silent (SNP) | VAF 136/466 reads (29%) | called by muse, mutect2, varscan2
- TAAR6 | c.906T>C p.Y302= | Silent (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
- CACNB2 | c.804+645_804+646del | Intron (DEL) | VAF 83/360 reads (23%) | called by mutect2, pindel, varscan2
- FBXO46 | c.*47C>A | 3'UTR (SNP) | VAF 44/234 reads (19%) | called by muse, mutect2, varscan2
- GPI | c.1399-16T>G | Intron (SNP) | VAF 155/682 reads (23%) | called by muse, mutect2, varscan2
- KLF6 | c.*140T>C | 3'UTR (SNP) | VAF 62/267 reads (23%) | called by muse, mutect2, varscan2
- MDM1 | c.-29G>C | 5'UTR (SNP) | VAF 15/90 reads (17%) | called by muse, mutect2, varscan2
- MMS19 | c.262+622G>T | Intron (SNP) | VAF 33/179 reads (18%) | called by muse, mutect2, varscan2
- RPAIN | c.313+13_313+15del | Intron (DEL) | VAF 22/96 reads (23%) | called by pindel, varscan2
- RPAIN | c.313+19C>A | Intron (SNP) | VAF 20/86 reads (23%) | called by muse, varscan2
- SAMD4A | c.197-14699G>C | Intron (SNP) | VAF 34/231 reads (15%) | called by muse, mutect2, varscan2
- WNK2 | c.6739+54_6739+61del | Intron (DEL) | VAF 48/236 reads (20%) | called by mutect2, pindel, varscan2
- XIRP2 | c.*608A>T | 3'UTR (SNP) | VAF 20/99 reads (20%) | called by muse, mutect2, varscan2
- ZNF587 | c.*48A>C | 3'UTR (SNP) | VAF 16/76 reads (21%) | called by muse, mutect2, varscan2
